Gene-level copy-number profile of tumor specimen TCGA-VQ-AA68-01A from TCGA case TCGA-VQ-AA68, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 52.9 years (19,304 days).
Specimen TCGA-VQ-AA68-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.16002eb5-12ab-4d01-8343-3131d0d44588.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA68-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd1f40e7-6a81-475e-b3ac-b4f122105597

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 1,330; copy number 2: 13,262; copy number 3: 18,425; copy number 4: 14,714; copy number 5: 8,371; copy number 6: 2,398; copy number 7: 127; copy number 8: 1,077; copy number 9: 76; copy number 10: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA68-01A-11D-A40Z-01): tumor purity 0.33, ploidy 6.01, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:157,739,010–157,740,456, 1 gene: AC006003.1.
- chr16:78,166,717–78,553,296, 8 genes: AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr20:14,554,384–15,280,873, 7 genes (within-gene range 0–3): MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,285 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:139,389,761–139,782,699, 9 genes, copy number 9 (within-gene range 6–9): AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P.
- chr6:62,460,940–63,779,336, 19 genes, copy number 7: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4.
- chr7:70,972–34,892,549, 606 genes, copy number 8 (broad region; genes not listed).
- chr7:35,036,836–62,275,678, 471 genes, copy number 8 (broad region; genes not listed).
- chr8:41,929,479–43,544,057, 55 genes, copy number 9: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2.
- chr11:132,284,302–132,404,060, 2 genes, copy number 7: NTM-IT, AP000843.1.
- chr11:132,525,809–132,773,371, 2 genes, copy number 7: U6, AP003784.1.
- chr12:38,532,895–39,059,933, 6 genes, copy number 9: AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1.
- chr12:66,347,431–67,069,162, 1 gene, copy number 9 (within-gene range 2–9): GRIP1.
- chr12:66,950,754–67,319,953, 5 genes, copy number 9 (within-gene range 4–9): AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1.
- chr13:21,483,834–21,704,498, 6 genes, copy number 7: H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9.
- chr13:22,803,145–23,970,188, 28 genes, copy number 7–10: SNORD36, RPL7AP73, IPMKP1, RFESDP1, LINC00621, BASP1P1, NUS1P2, AL157931.1, AL157931.2, HMGA1P6, RNY3P4, LINC00362, SGCG, RNU6-58P, TATDN2P3, SDAD1P4, SACS, RPLP1P13, SACS-AS1, LINC00327, LINC00352, TNFRSF19, MIPEP, MTCO3P2, PCOTH, C1QTNF9B, ANKRD20A19P, AL445985.2.
- chr13:23,979,810–24,035,027, 1 gene, copy number 10: AL445985.1.
- chr19:22,137,931–23,445,189, 71 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
